Surgical pathology report (de-identified scan), TCGA case TCGA-RD-A8N0, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Peter MacCallum Cancer Center, specimen TCGA-RD-A8N0-01A (Primary Tumor).

ICD-0-3

(Specimen Collected:

Comment for
HISTOPATHOLOGY REPORT

HISTO

REQUEST DETAILS
Gastrectomy.

Adenocarcinoma, diffuse type 8/45/13
Site: Gastric fundus C16.1
Greater curvature stomach C16.6
4/25/28/14

MACROSCOPIC DESCRIPTION

Specimen labelled "subtotal gastrectomy". The specimen is difficult to orientate but comprises a portion of stomach, 120 x 45 x 45mm. The specimen measures 120mm along the greater curvature where there is attached adipose tissue and omentum. The presumed proximal resection margin is stapled and is 45mm in length. The presumed distal resection margin is also stapled and is 35mm in length. Further adipose tissue is adherent to the lesser curvature. 35mm from the distal resection margin on the greater curvature of the specimen, is an ulcerated crater-like tumour with raised edges measuring 30mm in maximum dimension. There is thickening of the stomach wall in this region and the serosa beneath the tumour appears pale with some tethering of adipose tissue. The remaining gastric mucosa is unremarkable. Margins marked with black ink. Blocks selected 1.1-1.2 proximal resection margin, 1.3-1.4 distal resection margin, 1.5-1.6 tumour, 1.7 lesser curvature, 1.8 lesser curvature lymph nodes, 1.9-1.10 greater curvature lymph nodes.

MICROSCOPIC DESCRIPTION

There is an ulcer in the gastric wall, which has been re-epithelialized, but which extends into muscularis propria. At the base of the ulcer, and expanding the adjacent lamina propria is a population of atypical epithelioid cells with some gland formation. Similar atypical epithelioid cells arranged singly and in small clusters extend through the submucosa and muscularis propria to abut the serosa of the specimen and to infiltrate subserosal adipose tissue. Perineural and intraneural invasion is identified. There is no adjacent mucosal dysplasia or intestinal metaplasia. The tumour is clear of the proximal and distal resection margins. Elsewhere, there is a moderately dense infiltrate of acute and chronic inflammatory cells within lamina propria of body and antral mucosa, and small numbers of Helicobacter pylori are identified. Numerous small deposits of tumour are identified within adipose tissue from the lesser and greater curvatures. Twenty lymph nodes are identified within fat from the lesser curve, three of which contain tumour. Sixteen lymph nodes are identified within fat from the greater curve, seven of which contain tumour. Duodenal mucosa at the distal resection margin is unremarkable.

DIAGNOSIS

Subtotal gastrectomy: Poorly differentiated adenocarcinoma, diffuse type, with extension through muscularis propria to the serosal margin. Proximal and distal margins are free of tumour. There is metastatic adenocarcinoma within ten of thirty-six lymph nodes identified.

Criteria	W 10/23/13	Yes	No

Source: NCI Genomic Data Commons file fcbd1fa2-afb1-4a50-87a2-92b777aeb6bb (TCGA-RD-A8N0.898094E2-CFFA-4117-9728-6290DABE3124.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).